Gene-level copy-number profile of tumor specimen TCGA-QM-A5NM-01A from TCGA case TCGA-QM-A5NM, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 67.8 years (24,781 days).
Specimen TCGA-QM-A5NM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.9ab3b63a-5d37-4ea9-84cc-70acc3b641de.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QM-A5NM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bf792a5-63cf-49c2-87ed-6ba01c782328

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 6; copy number 2: 7,009; copy number 3: 13,837; copy number 4: 29,325; copy number 5: 4,140; copy number 6: 5,487; copy number 9: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QM-A5NM-01A-11D-A28Q-01): tumor purity 0.87, ploidy 3.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:99,355,337–99,377,240, 1 gene (within-gene range 0–2): NAMA.
- chr9:99,359,336–99,371,887, 2 genes (within-gene range 0–2): AL137067.3, AL137067.1.
- chr13:48,296,162–48,303,661, 1 gene: RB1-DT.
- chr13:48,316,863–48,341,330, 3 genes: PPP1R26P1, PCNPP5, AL392048.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:140,657,900–141,002,216, 1 gene, copy number 9 (within-gene range 6–9): PTK2.
- chr8:140,820,599–141,195,808, 5 genes, copy number 9: AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
